Somatic mutation profile of tumor specimen TARGET-10-PARHAN-09A (aliquot TARGET-10-PARHAN-09A-01D) from TARGET case TARGET-10-PARHAN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,458 days).
Specimen TARGET-10-PARHAN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 509c5a07-9963-4cfe-930f-55001096ac4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHAN-10A (Blood Derived Normal), aliquot TARGET-10-PARHAN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45749cf8-6307-4f9b-891a-85c681473d78

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Ins 3, Silent 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- AXIN2 | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs373911689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYSL4 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs757669088; called by muse, varscan2
- PAX5 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM1514451, COSV63906029; called by muse, mutect2, varscan2
- SLC7A8 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1474532630; called by muse, mutect2, varscan2
- SPATA16 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs926855937; called by muse, mutect2, varscan2
- TENM4 | c.4516G>A p.V1506I | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.202); catalogued as rs550019697, COSV99581049; called by muse, mutect2, varscan2
- UNC13A | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs868745719; called by muse, mutect2, varscan2
- CFH | c.3492A>G p.L1164= | Splice Region (SNP) | VAF 83/186 reads (45%) | called by muse, mutect2, varscan2
- EPHA6 | c.2977A>G p.M993V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- FER1L5 | c.1639C>T p.P547S (on ENST00000623019; = p.P552S on NM_001293083.2) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PAX5 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PIWIL4 | c.2110_2111insGAAA p.I704Rfs*3 | Frame Shift Ins (INS) | VAF 41/86 reads (48%) | called by mutect2, pindel, varscan2
- PPP4R3A | c.118_119insG p.L40Rfs*6 | Frame Shift Ins (INS) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- RNF10 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- UBA1 | c.134_137dup p.S46Rfs*3 | Frame Shift Ins (INS) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- OR52L1 | c.324C>T p.H108= | Silent (SNP) | VAF 64/132 reads (48%) | catalogued as rs370634023, COSV59985885; called by muse, mutect2, varscan2
- TIAM1 | c.4401G>A p.P1467= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs753140945; called by muse, mutect2, varscan2
- HBE1 | c.-267+102599G>A | Intron (SNP) | VAF 5/100 reads (5%) | catalogued as rs1049547499; called by muse, mutect2
